Gene-level copy-number profile of tumor specimen TCGA-44-6774-01A from TCGA case TCGA-44-6774, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 56.0 years (20,462 days).
Specimen TCGA-44-6774-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.47086a80-52bf-48e9-8766-67e6df727911.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-6774-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bda3fc28-6cc1-4990-a00d-8a36e343cdb8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,894; copy number 2: 42,612; copy number 3: 4,276; copy number 4: 2,276; copy number 5: 341; copy number 6: 158; copy number 7: 2; copy number 8: 48; copy number 12: 4; copy number 15: 14; copy number 22: 77; copy number 30: 6; copy number 34: 12; copy number 35: 15; copy number 40: 72; copy number 43: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-6774-01A-21D-1854-01): tumor purity 0.45, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 756 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:5,140,330–5,422,116, 7 genes, copy number 12–30 (within-gene range 3–30): ADAMTS16, AC022424.1, ALG3P1, AC091978.1, MTCO1P30, MTCO2P30, MTCO1P31.
- chr5:7,980,146–8,080,761, 3 genes, copy number 12: RNU1-76P, AC116361.1, AC091941.1.
- chr5:15,500,180–15,939,795, 1 gene, copy number 6 (within-gene range 4–6): FBXL7.
- chr5:15,935,182–16,180,762, 4 genes, copy number 6 (within-gene range 3–6): MIR887, RNA5SP178, MARCHF11, MARCHF11-AS1.
- chr5:17,065,598–17,276,843, 2 genes, copy number 34 (within-gene range 3–34): BASP1, BASP1-AS1.
- chr5:17,156,971–17,443,619, 10 genes, copy number 34 (within-gene range 4–34): RNA5SP180, DCAF13P2, RNU6-1003P, AC026785.1, RN7SKP133, FTH1P10, AC026785.2, AC026785.3, LINC02111, LINC02217.
- chr5:20,606,710–23,014,527, 19 genes, copy number 6: LINC02146, LINC02241, AC138938.1, AC140168.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1.
- chr5:35,852,695–39,572,639, 72 genes, copy number 40 (broad region; genes not listed).
- chr8:75,407,914–75,566,834, 1 gene, copy number 8 (within-gene range 4–8): HNF4G.
- chr8:79,259,402–111,236,203, 526 genes, copy number 5–43 (within-gene range 5–54) (broad region; genes not listed).
- chr8:111,380,603–111,380,868, 1 gene, copy number 6: SERPINA15P.
- chr8:127,578,473–128,388,636, 17 genes, copy number 7–35: AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1.
- chr14:33,924,227–38,041,442, 92 genes, copy number 6–22 (broad region; genes not listed).
- chr14:40,630,006–40,905,513, 1 gene, copy number 15 (within-gene range 2–18): AL390800.1.

Autosomal genes at a single copy (total copy number 1): 9,894. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
